Somatic mutation profile of tumor specimen BA2925D (aliquot aq-BA2925D) from BEATAML1.0 case 2201, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia with myelodysplasia-related changes; Tissue or organ of origin: Bone marrow; Age at diagnosis: 77.3 years (28,221 days).
Specimen BA2925D: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 85ffccbd-261d-475b-989e-2375a0144372.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2128D (Solid Tissue Normal), aliquot aq-BA2128D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c9d28e88-3149-4e64-bd3c-8d46ea98a159

The open-access MAF lists 6 somatic variants for this specimen: 4 protein-altering or splice-affecting, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, Intron 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CCDC96 | c.599G>T p.R200L | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); called by muse, mutect2
- KMT5B | c.654-1G>A p.X218_splice | Splice Site (SNP) | VAF 26/74 reads (35%) | called by muse, mutect2, varscan2
- SHB | c.406G>T p.A136S | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT tolerated (0.48); PolyPhen probably damaging (0.982); called by muse, mutect2
- SLC12A1 | c.1511C>A p.T504K | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- IGFN1 | c.1241+2661G>A | Intron (SNP) | VAF 20/57 reads (35%) | catalogued as COSV55171371; called by muse, mutect2, varscan2
- RC3H2 | c.583+47G>T | Intron (SNP) | VAF 5/61 reads (8%) | called by muse, mutect2
